Somatic mutation profile of tumor specimen 0DMWTV from CCDI case PBCBAE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Dysembryoplastic neuroepithelial tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.7 years (2,441 days).
Specimen 0DMWTV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5e18c27-8678-4063-ad38-7169f247307b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMWU2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6167f6f-3468-424e-9b88-531ba59f68fb

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.709); catalogued as rs1324156819, COSV58336345; called by muse, mutect2
- C2CD3 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 105/296 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.071); called by muse, mutect2, varscan2
